Somatic mutation profile of tumor specimen TARGET-10-PAPAZA-09A (aliquot TARGET-10-PAPAZA-09A-01D) from TARGET case TARGET-10-PAPAZA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.1 years (2,967 days).
Specimen TARGET-10-PAPAZA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e177feb3-869f-48d8-bb74-2549619f9782.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPAZA-14A (Bone Marrow Normal), aliquot TARGET-10-PAPAZA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19dad513-9dc6-46c5-a4a1-46f1651752b3

The open-access MAF lists 28 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Intron 6, Silent 3, Splice Site 2, Frame Shift Ins 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.176C>A p.A59E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55568979, COSV55604554, COSV55904854; called by muse, mutect2, varscan2
- AK5 | c.770G>T p.R257L (on ENST00000354567 / NM_174858.3; = p.R231L on NM_012093.4) | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60971016; called by muse, mutect2
- ARHGAP21 | c.4712C>T p.T1571M | Missense Mutation (SNP) | VAF 82/186 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs148071624; called by muse, mutect2, varscan2
- BCLAF3 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100503212; called by muse, mutect2, varscan2
- CFAP61 | c.2408C>T p.T803M | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as rs780255308, COSV55619741, COSV55624296; called by muse, mutect2, varscan2
- CXCR4 | c.1031_1032insGAACCCCC p.E345Nfs*24 | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | catalogued as COSV54015322; called by mutect2, pindel
- DNAH5 | c.10319C>A p.A3440D | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54209694; called by muse, mutect2, varscan2
- LRRC30 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs764413451; called by muse, mutect2, varscan2
- C4orf54 | c.2551G>A p.A851T | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FAM217B | c.153C>A p.S51R | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- GAS2L2 | c.1636G>T p.A546S | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2
- KRT222 | c.35C>A p.A12E | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.969); called by muse, mutect2
- OCLN | c.891+1G>A p.X297_splice | Splice Site (SNP) | VAF 36/144 reads (25%) | called by muse, mutect2, varscan2
- PCDH7 | c.2673G>C p.L891F | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- PKLR | c.507+1dup p.X169_splice | Splice Site (INS) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- PRPF8 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 5/147 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SERPINB7 | c.1081T>C p.F361L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR1A2 | c.573C>T p.D191= | Silent (SNP) | VAF 115/254 reads (45%) | catalogued as rs760105962, COSV67936200; called by muse, mutect2, varscan2
- SLC9A4 | c.1234C>A p.R412= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as rs766908354, COSV54828977; called by muse, mutect2, varscan2
- TENT4B | c.1851G>A p.P617= (on ENST00000561678 / NM_001365323.2; = p.P602= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 81/174 reads (47%) | catalogued as rs755481341, COSV62547598; called by muse, mutect2, varscan2
- AC093791.1 | n.401G>C | RNA (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- KIF5C | c.1906-78T>C | Intron (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- LEAP2 | c.58-78C>T | Intron (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- POLE | c.5552+49G>T | Intron (SNP) | VAF 10/22 reads (45%) | called by muse, varscan2
- SIRPB1 | c.433+156G>T | Intron (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2
- SNRPG | c.180+703A>T | Intron (SNP) | VAF 52/105 reads (50%) | called by muse, mutect2, varscan2
- SYCE1 | c.137-67G>A | Intron (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- TMEM135 | c.*74G>A | 3'UTR (SNP) | VAF 60/127 reads (47%) | catalogued as rs1194279740; called by muse, mutect2, varscan2
